Somatic mutation profile of tumor specimen C3N-00313-03 (aliquot CPT0011410009) from CPTAC case C3N-00313, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 31.8 years (11,619 days).
Specimen C3N-00313-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 868e6467-d0a7-4546-946e-fea4d0b0bd19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00313-31 (Blood Derived Normal), aliquot CPT0012040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9eab1f1c-49f4-471d-b7a3-3050e6097aa2

The open-access MAF lists 87 somatic variants for this specimen: 66 protein-altering or splice-affecting, 11 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 11, Frame Shift Del 8, Splice Site 4, Intron 4, 5'UTR 3, Splice Region 3, In Frame Del 3, 3'UTR 2, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11B2 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 94/350 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs28931609, CM920221; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.1027-17_1034del p.X343_splice | Splice Site (DEL) | VAF 64/396 reads (16%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADCY5 | c.2435G>T p.C812F | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100568256; called by muse, mutect2, varscan2
- ARHGEF10L | c.258-2A>G p.X86_splice | Splice Site (SNP) | VAF 20/69 reads (29%) | catalogued as rs1315777801; called by muse, varscan2
- CELF3 | c.773-4C>T | Splice Region (SNP) | VAF 25/101 reads (25%) | catalogued as rs557271767; called by muse, mutect2, varscan2
- CSMD3 | c.3122G>A p.R1041K (on ENST00000297405 / NM_001363185.1; = p.R937K on NM_052900.3) | Missense Mutation (SNP) | VAF 65/282 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.578); catalogued as rs865789863, COSV52161818; called by muse, mutect2, varscan2
- DMRTB1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV65113242; called by muse, mutect2, varscan2
- DSN1 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 137/314 reads (44%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.659); catalogued as COSV101041115, COSV65518842; called by muse, mutect2, varscan2
- KLF15 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1268011776; called by muse, mutect2, varscan2
- MSLNL | c.1898C>A p.T633N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); catalogued as rs776461955; called by muse, mutect2, varscan2
- MYNN | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 124/281 reads (44%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1170682896; called by muse, mutect2, varscan2
- NT5DC3 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.784); catalogued as rs1478255341, COSV67323040; called by muse, mutect2, varscan2
- OTUB2 | c.38G>A p.C13Y | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.35); catalogued as COSV52573316; called by muse, mutect2, varscan2
- PLEKHA5 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 134/287 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.034); catalogued as rs772807720; called by muse, mutect2, varscan2
- PROX1 | c.1471T>A p.Y491N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99798480; called by muse, mutect2, varscan2
- PTEN | c.136T>A p.Y46N | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64296748, COSV64297491; called by muse, mutect2, varscan2
- PXDN | c.3481C>T p.R1161W | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53226287; called by muse, mutect2, varscan2
- SLC35F3 | c.293T>A p.F98Y (on ENST00000366617 / NM_001300845.1; = p.F167Y on NM_173508.4) | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV64020504; called by muse, mutect2, varscan2
- SPTBN5 | c.5888G>A p.R1963H | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as rs756663149; called by muse, mutect2, varscan2
- TMEM37 | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV99191635; called by muse, mutect2, varscan2
- TMPRSS3 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 231/621 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs144556872; called by muse, mutect2, varscan2
- VWA3A | c.2339C>T p.S780F | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV100240699; called by muse, mutect2, varscan2
- AASDH | c.793T>G p.S265A | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM28 | c.881A>C p.Q294P | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD17 | c.7730C>G p.T2577R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- AQP3 | c.381_383del p.I127_W128delinsM | In Frame Del (DEL) | VAF 60/200 reads (30%) | called by mutect2, pindel, varscan2
- ARFGAP3 | c.542A>C p.E181A | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL9L | c.1960C>G p.Q654E | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- C9orf43 | c.737_738del p.L246* | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- CDC42EP4 | c.305T>C p.M102T | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CDKN2AIP | c.1099del p.A367Lfs*5 | Frame Shift Del (DEL) | VAF 43/164 reads (26%) | called by mutect2, pindel, varscan2
- CELF3 | c.773-5C>A | Splice Region (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- CHMP2B | c.94del p.R32Efs*4 | Frame Shift Del (DEL) | VAF 100/268 reads (37%) | called by mutect2, pindel, varscan2
- CTR9 | c.1473C>G p.Y491* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | called by muse, mutect2, varscan2
- DST | c.6038G>C p.G2013A | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- FAM221A | c.638del p.X213_splice | Splice Site (DEL) | VAF 60/179 reads (34%) | called by mutect2, pindel, varscan2
- FCGBP | c.7878C>G p.D2626E | Missense Mutation (SNP) | VAF 78/655 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2
- ICAM3 | c.1193-18_1196del p.X398_splice | Splice Site (DEL) | VAF 28/96 reads (29%) | called by mutect2, pindel
- ITIH2 | c.540del p.E180Dfs*7 | Frame Shift Del (DEL) | VAF 43/200 reads (22%) | called by mutect2, pindel, varscan2
- JMY | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLKB1 | c.1351A>C p.I451L | Missense Mutation (SNP) | VAF 87/315 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KRTAP19-5 | c.155G>C p.G52A | Missense Mutation (SNP) | VAF 139/385 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LRRC30 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NHS | c.3168A>T p.K1056N | Missense Mutation (SNP) | VAF 121/407 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- OR4D9 | c.362_379del p.D121_S127delinsA | In Frame Del (DEL) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- OSGIN2 | c.122A>T p.Y41F | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- OTUD5 | c.1331G>C p.G444A | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- P2RX4 | c.610A>C p.N204H | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE7A | c.298_299insT p.E100Vfs*20 (on ENST00000401827 / NM_001242318.3; = p.E74Vfs*20 on NM_002603.4) | Frame Shift Ins (INS) | VAF 33/101 reads (33%) | called by mutect2, pindel, varscan2
- PDGFRL | c.829_839del p.L277Kfs*35 | Frame Shift Del (DEL) | VAF 40/261 reads (15%) | called by mutect2, pindel
- PFDN2 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PIK3R1 | c.1712_1729del p.I571_T576del (on ENST00000521381 / NM_181523.3; = p.I301_T306del on NM_181504.4) | In Frame Del (DEL) | VAF 25/106 reads (24%) | called by mutect2, pindel, varscan2
- PRPF3 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRSS8 | c.1014_1015del p.W339Afs*26 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- RBM47 | c.813del p.G272Afs*27 | Frame Shift Del (DEL) | VAF 93/306 reads (30%) | called by mutect2, pindel, varscan2
- RRM2 | c.567A>G p.E189= | Splice Region (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2
- SKOR1 | c.867del p.A290Pfs*85 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- SNF8 | c.-11_15del | Translation Start Site (DEL) | VAF 18/108 reads (17%) | called by mutect2, pindel
- SPATA2L | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- SYNE1 | c.10126G>A p.A3376T (on ENST00000367255 / NM_182961.4; = p.A3383T on NM_033071.3) | Missense Mutation (SNP) | VAF 76/305 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TPP1 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- UBC | c.1634T>C p.I545T | Missense Mutation (SNP) | VAF 146/496 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- WASHC2A | c.2870T>G p.I957R | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- WDR35 | c.1703C>T p.T568I (on ENST00000345530 / NM_001006657.2; = p.T557I on NM_020779.4) | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- WNT8B | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN29 | c.2504A>C p.K835T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.189); called by muse, varscan2
- ACACA | c.3408A>G p.Q1136= | Silent (SNP) | VAF 57/207 reads (28%) | called by muse, mutect2, varscan2
- CCDC180 | c.1116G>T p.L372= | Silent (SNP) | VAF 51/157 reads (32%) | called by muse, mutect2, varscan2
- DSCAML1 | c.4935A>G p.E1645= (on ENST00000321322; = p.E1585= on NM_020693.4) | Silent (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- DST | c.6039A>G p.G2013= | Silent (SNP) | VAF 67/225 reads (30%) | called by muse, mutect2, varscan2
- EPB42 | c.417C>T p.N139= (on ENST00000441366 / NM_001114134.2; = p.N169= on NM_000119.3) | Silent (SNP) | VAF 83/298 reads (28%) | catalogued as rs1197358075; called by muse, mutect2, varscan2
- GPR158 | c.117C>A p.T39= | Silent (SNP) | VAF 61/156 reads (39%) | called by muse, mutect2, varscan2
- LPAR3 | c.423C>G p.T141= | Silent (SNP) | VAF 73/246 reads (30%) | called by muse, mutect2, varscan2
- MSLNL | c.1899C>T p.T633= | Silent (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- NFXL1 | c.606G>A p.V202= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as rs532705810; called by muse, mutect2, varscan2
- TOMM20 | c.414C>T p.S138= | Silent (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.771A>T p.A257= | Silent (SNP) | VAF 50/185 reads (27%) | called by muse, mutect2, varscan2
- C4orf36 | c.65+1361C>G | Intron (SNP) | VAF 23/106 reads (22%) | catalogued as rs753310845; called by muse, mutect2, varscan2
- FAM183BP | n.896C>T | RNA (SNP) | VAF 113/286 reads (40%) | catalogued as rs773686260; called by muse, mutect2, varscan2
- MMACHC | c.-25G>A | 5'UTR (SNP) | VAF 70/268 reads (26%) | catalogued as rs750522696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPHLN1 | c.1126-1020G>A | Intron (SNP) | VAF 83/163 reads (51%) | catalogued as rs1329908336; called by muse, mutect2, varscan2
- SFPQ | c.*2T>A | 3'UTR (SNP) | VAF 47/143 reads (33%) | called by muse, mutect2, varscan2
- THBS1 | c.*528C>G | 3'UTR (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- TMEM25 | c.71-17C>A | Intron (SNP) | VAF 4/9 reads (44%) | called by muse, varscan2
- UHRF2 | c.384+1547A>T | Intron (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- WASHC2C | c.-25G>C | 5'UTR (SNP) | VAF 26/134 reads (19%) | called by muse, mutect2, varscan2
- WASHC2C | c.-24A>G | 5'UTR (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
